MMRF case MMRF_1773 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ea1a2862-60a9-485e-ae35-ec35ad856cc7

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 44.3 years (16,177 days); ISS stage: I; Days to last known disease status: 1,079 days (3.0 years); Days to last follow up: 1,079 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 191 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 722 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 117 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 217 days; Days to treatment end: 218 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 220 days; Days to treatment end: 220 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 303 days; Days to treatment end: 710 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 235 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 106 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 8.34 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 266 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.942 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.27 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.79 mmol/L.
- Day 358 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.914 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 5.05 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.36 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.01 mmol/L.
- Day 442 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.743 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 6.59 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.24 ×10⁹/L; Platelets 394 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.29 mmol/L.
- Day 554 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.182 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.74 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 638 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.233 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 3.85 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.24 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.
- Day 722 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.838 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 4.69 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.67 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 813: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 911 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 7.34 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 995 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.842 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.58 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 1,079 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.888 mg/dL; Immunoglobulin G 7.45 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day 1: Weight: 101 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1773_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1773_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
